Somatic mutation profile of tumor specimen 0DG87S from CCDI case PBBSVA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Rhabdoid tumor, NOS; Tissue or organ of origin: Vertebral column; Age at diagnosis: 6.6 years (2,405 days).
Specimen 0DG87S: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 131acb65-4935-4eaf-91a2-fe040df0d6a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DG84G (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/24ff143c-821f-42e0-95a6-7119f8e9c37c

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 3, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERCC4 | c.2102G>A p.R701H | Missense Mutation (SNP) | VAF 308/735 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs762543560, COSV61311784; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IQCM | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 367/959 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs945261980; called by muse, mutect2, varscan2
- CCDC138 | c.561A>G p.I187M | Missense Mutation (SNP) | VAF 18/530 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- DLG2 | c.1025G>A p.R342K | Missense Mutation (SNP) | VAF 298/659 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- MAP3K20 | c.1593G>A p.S531= | Silent (SNP) | VAF 316/771 reads (41%) | catalogued as rs201232328; called by muse, mutect2, varscan2
- RPE65 | c.1545G>A p.R515= | Silent (SNP) | VAF 372/885 reads (42%) | catalogued as COSV99253597; called by muse, mutect2, varscan2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 28/1037 reads (3%) | called by muse, mutect2
- STOML1 | c.*18C>A | 3'UTR (SNP) | VAF 114/251 reads (45%) | called by mutect2, varscan2
